TCGA case TCGA-23-2084 — Ovarian Serous Cystadenocarcinoma (TCGA-OV)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Cystic, Mucinous and Serous Neoplasms; Primary site: Ovary; Tissue source site: Cedars Sinai. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/2cb82948-7cbe-4b6c-8414-c02f662de2d0

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Age at index: 45 years; Vital status: Dead; Days to death: 1,516 days (4.2 years); Population group: Ashkenazi Jew.

Diagnoses (2)
1. Serous cystadenocarcinoma, NOS (the primary disease): ICD-O-3 morphology code: 8441/3; ICD-10 code: C56.9; Tissue or organ of origin: Ovary; Site of resection or biopsy: Ovary; Laterality: Right; Classification of tumor: primary; Age at diagnosis: 45.2 years (16,493 days); Year of diagnosis: 2000; Method of diagnosis: Surgical Resection; FIGO stage: Stage IV; Tumor grade: G3; Prior treatment: No.
   Pathology details: Lymphatic invasion present: Yes; Residual tumor measurement: No macroscopic disease; Vascular invasion present: Yes.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Carboplatin; Treatment intent type: Adjuvant; Days to treatment start: 6 days; Days to treatment end: 155 days; Number of cycles: 8; Treatment dose: 4,240 mg; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Paclitaxel; Treatment intent type: Adjuvant; Days to treatment start: 6 days; Days to treatment end: 155 days; Number of cycles: 8; Treatment dose: 2,200 mg; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Cisplatin; Initial disease status: Recurrent Disease; Days to treatment start: 631 days (1.7 years); Days to treatment end: 701 days (1.9 years); Number of cycles: 6; Treatment dose: 700 mg; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Gemcitabine Hydrochloride; Initial disease status: Recurrent Disease; Days to treatment start: 631 days (1.7 years); Days to treatment end: 701 days (1.9 years); Number of cycles: 6; Treatment dose: 12,600 mg; Route of administration: Intravenous.
   Treatment given: Treatment type: Immunotherapy (Including Vaccines); Therapeutic agents: Clinical Trial; Initial disease status: Progressive Disease; Days to treatment start: 1,127 days (3.1 years); Days to treatment end: 1,169 days (3.2 years); Number of cycles: 3; Treatment dose: 1,680 mg; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Pegylated Liposomal Doxorubicin Hydrochloride; Initial disease status: Progressive Disease; Days to treatment start: 1,183 days (3.2 years); Days to treatment end: 1,240 days (3.4 years); Number of cycles: 3; Treatment dose: 195 mg; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Docetaxel; Initial disease status: Progressive Disease; Days to treatment start: 1,261 days (3.5 years); Days to treatment end: 1,302 days (3.6 years); Number of cycles: 3; Treatment dose: 360 mg; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Topotecan; Initial disease status: Progressive Disease; Days to treatment start: 1,324 days (3.6 years); Days to treatment end: 1,359 days (3.7 years); Number of cycles: 4; Treatment dose: 14 mg; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Carboplatin; Initial disease status: Progressive Disease; Days to treatment start: 1,381 days (3.8 years); Days to treatment end: 1,401 days (3.8 years); Number of cycles: 2; Treatment dose: 920 mg; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Ifosfamide; Initial disease status: Progressive Disease; Days to treatment start: 1,381 days (3.8 years); Days to treatment end: 1,401 days (3.8 years); Number of cycles: 2; Treatment dose: 1,615 mg; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Cisplatin; Initial disease status: Progressive Disease; Days to treatment start: 1,425 days (3.9 years); Days to treatment end: 1,425 days (3.9 years); Number of cycles: 1; Treatment dose: 100 mg; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Ifosfamide; Initial disease status: Progressive Disease; Days to treatment start: 1,425 days (3.9 years); Days to treatment end: 1,425 days (3.9 years); Number of cycles: 1; Treatment dose: 730 mg; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Etoposide; Initial disease status: Progressive Disease; Days to treatment start: 1,457 days (4.0 years); Days to treatment end: 1,485 days (4.1 years); Number of cycles: 2; Treatment dose: 100 mg; Route of administration: Oral.
   Recorded as not given: adjuvant Radiation Therapy, NOS.
2. Recurrence of diagnosis 1 (Serous cystadenocarcinoma, NOS). Age at diagnosis: 46.9 years (17,112 days); Days to diagnosis: 619 days (1.7 years); Prior treatment: Yes.
   Treatment given: Treatment type: Surgery, NOS; Days to treatment start: 627 days (1.7 years).
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Initial disease status: Recurrent Disease.
   Recorded as not given: Radiation Therapy, NOS; Radiation Therapy, NOS, for recurrent disease.

Follow-up (3 entries)
- Day 619 (post initial treatment): Progression or recurrence: Yes; Days to recurrence: 619 days (1.7 years); Evidence of recurrence type: Convincing Image Source.
- Days to follow up: 1,516 days (4.2 years); Disease response: With Tumor.
- Progression or recurrence: Yes; Progression or recurrence type: Locoregional; Evidence of recurrence type: Convincing Image Source; Timepoint: Post Initial Treatment.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-23-2084-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Longest dimension: 1.4; Intermediate dimension: 1.1; Shortest dimension: 0.5.
  Slide TCGA-23-2084-01A-01-BS1: Section location: Top; Percent tumor cells: 90; Percent tumor nuclei: 90; Percent normal cells: 1; Percent necrosis: 0; Percent stromal cells: 9.
  Slide TCGA-23-2084-01A-02-BS2: Section location: Bottom; Percent tumor cells: 85; Percent tumor nuclei: 85; Percent normal cells: 1; Percent necrosis: 0; Percent stromal cells: 14.
- Sample TCGA-23-2084-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-23-2084-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Histologic diagnosis: Serous Cystadenocarcinoma; Tumor status: With tumor; History neoadjuvant treatment: No; Jewish religion heritage indicator: Ashkenazi; Anatomic organ subdivision: Right; Method initial path diagnosis: Tumor resection; Lymphovascular invasion indicator: Yes.
- Drug treatment 1: Therapy regimen: Progression.
- Drug treatment 1, Route of administrations: Route of administration: IV.
- Drug treatment 2: Pharmaceutical therapy drug name: Taxotere; Therapy regimen: Progression.
- Drug treatment 3: Pharmaceutical therapy drug name: Etoposide (VP16); Therapy regimen: Progression.
- Drug treatment 3, Route of administrations: Route of administration: PO.
- Drug treatment 4: Pharmaceutical therapy drug name: Gemzar.
- Drug treatment 7: Pharmaceutical therapy drug name: Doxil; Therapy regimen: Progression.
- Drug treatment 12: Pharmaceutical therapy drug name: Rhumab/Ind; Therapy regimen: Progression.
- Follow-up form: Treatment outcome first course: Complete Remission/Response; Tumor status: With tumor.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 1,516 days; disease-specific survival: event (death attributed to the disease, the Clinical Data Resource's approximation), 1,516 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 619 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-23-2084-01A-02D-0663-01): tumor purity 0.69, ploidy 3.25, whole-genome doublings 1.
